Gene-level copy-number profile of tumor specimen BLGSP-71-06-00156-01A from CGCI case BLGSP-71-06-00156, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-06-00156-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Buccal Mucosa; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a897facb-b67d-4950-a08f-b95dda231daf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00156-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/0b53fd0a-d620-4142-8ad1-3ae513c2ed80

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,605; copy number 2: 54,965; copy number 3: 208; copy number 7: 103; copy number 15: 26.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 129 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:89,991,831–99,583,180, 129 genes, copy number 7–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 749. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
